Somatic mutation profile of tumor specimen TCGA-D7-8573-01A (aliquot TCGA-D7-8573-01A-11D-2340-08) from TCGA case TCGA-D7-8573, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 57.4 years (20,963 days).
Specimen TCGA-D7-8573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14f3ff4b-ab67-456f-bc34-dd73f0226a99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-8573-10A (Blood Derived Normal), aliquot TCGA-D7-8573-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc05041c-5ac6-4452-a505-ae09843ca88d

The open-access MAF lists 87 somatic variants for this specimen: 64 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 21, Splice Site 2, In Frame Del 1, RNA 1, Nonsense Mutation 1, Intron 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121_141del p.T41_S47del | In Frame Del (DEL) | VAF 15/45 reads (33%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCA13 | c.2820A>C p.E940D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV70025519, COSV70028233; called by muse, mutect2, varscan2
- ACACB | c.5101C>G p.L1701V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.392); catalogued as COSV58146338; called by muse, mutect2, varscan2
- ACSBG1 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs201367266, COSV51910906; called by muse, mutect2, varscan2
- ADAMTS1 | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs770859188, COSV53173406; called by muse, mutect2, varscan2
- ADGRB3 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs764710020, COSV53234852, COSV99483148; called by muse, mutect2, varscan2
- AKT3 | c.860T>G p.I287S | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55632534; called by muse, mutect2, varscan2
- ALYREF | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV58669151, COSV58669210; called by muse, mutect2, varscan2
- ARFGEF3 | c.3515C>T p.S1172F | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV52462367; called by muse, mutect2
- ATM | c.1237C>A p.L413I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53774030; called by muse, varscan2
- BHLHE23 | c.329G>A p.R110Q (on ENST00000370346; = p.R126Q on NM_080606.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64846602; called by muse, mutect2, varscan2
- BICD1 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1009886917, COSV55681459; called by muse, mutect2, varscan2
- DBP | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV50034178; called by muse, mutect2, varscan2
- DENND3 | c.836A>T p.E279V | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52806773; called by muse, mutect2
- DOCK10 | c.2206C>T p.H736Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51427569; called by muse, mutect2, varscan2
- DTNA | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV52019665; called by muse, mutect2, varscan2
- EGF | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54484599; called by muse, mutect2, varscan2
- FILIP1 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 117/279 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs755925479, COSV52727083; called by muse, mutect2, varscan2
- FOXI1 | c.1016A>C p.N339T | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100089514; called by muse, mutect2, varscan2
- FOXI1 | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV100089516; called by muse, mutect2, varscan2
- GABRA1 | c.309A>C p.K103N | Missense Mutation (SNP) | VAF 82/114 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50119054; called by muse, mutect2, varscan2
- GABRA5 | c.324G>T p.R108S | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59485758; called by muse, mutect2, varscan2
- HCK | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 81/130 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs765715998, COSV52946751; called by muse, mutect2, varscan2
- HMOX1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1297383655, COSV53341282; called by muse, mutect2, varscan2
- HPS3 | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs527240120, COSV52834020; called by muse, mutect2, varscan2
- ITGA6 | c.689A>C p.N230T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV51263167; called by muse, mutect2
- JUP | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as rs782188536, COSV60278780; called by muse, mutect2, varscan2
- KLRC2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67900606; called by muse, mutect2, varscan2
- LETM1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs762433668, COSV57104375; called by muse, mutect2, varscan2
- LINGO1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as rs1414762142, COSV62438539, COSV62438820; called by muse, mutect2
- MCM3 | c.1852G>A p.A618T (on ENST00000229854 / NM_001366374.2; = p.A608T on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.884); catalogued as rs754057696, COSV57719382; called by muse, mutect2, varscan2
- MDN1 | c.12446G>A p.R4149H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs77256291; called by muse, mutect2, varscan2
- NLRP13 | c.2337G>T p.Q779H | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV61624016; called by muse, mutect2, varscan2
- NOM1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs138117452; called by muse, mutect2, varscan2
- NPEPL1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs370845185; called by muse, mutect2, varscan2
- PCDHGA4 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as rs760842215, COSV53930460, COSV54016618; called by muse, mutect2, varscan2
- PCSK5 | c.1107+1G>A p.X369_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV65096307; called by muse, mutect2, varscan2
- PDE10A | c.1300T>C p.S434P | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63106012; called by muse, mutect2, varscan2
- PDGFRB | c.1709A>C p.E570A | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55809981; called by muse, mutect2, varscan2
- PEG10 | c.391C>T p.R131C (on ENST00000482108 / NM_001040152.2; = p.R165C on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV71788681; called by muse, mutect2, varscan2
- PRRC2A | c.6469C>T p.R2157C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs781602439, COSV52991027, COSV99277245; called by muse, mutect2, varscan2
- PRUNE2 | c.4787T>C p.V1596A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV65047794; called by muse, mutect2, varscan2
- QSER1 | c.3094A>T p.S1032C (on ENST00000399302; = p.S1161C on NM_001076786.3) | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV67901790; called by muse, mutect2, varscan2
- RDH16 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs201496901, COSV62458112; called by muse, mutect2, varscan2
- RPAP3 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV50042940; called by muse, mutect2, varscan2
- SERPINE3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs116923084, COSV68545858; called by muse, mutect2
- SHANK1 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53262026; called by muse, mutect2, varscan2
- SHPRH | c.4793A>G p.H1598R (on ENST00000275233 / NM_001042683.3; = p.H1602R on NM_173082.3) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV51617606; called by muse, mutect2, varscan2
- SLC37A3 | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as COSV58268527; called by muse, mutect2, varscan2
- SOS1 | c.3874G>T p.V1292F | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); catalogued as COSV67677638; called by muse, mutect2
- SP8 | c.601G>A p.E201K (on ENST00000361443 / NM_198956.4; = p.E219K on NM_182700.6) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV63866960; called by muse, mutect2
- TJP2 | c.2213C>G p.P738R | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55274105; called by muse, mutect2, varscan2
- TMEM91 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 64/682 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV55372328; called by muse, mutect2
- TMPPE | c.161C>G p.S54W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV56566867, COSV56567950; called by muse, mutect2, varscan2
- TSPAN31 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57277160; called by muse, mutect2, varscan2
- TYR | c.1410A>C p.Q470H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV54485886; called by muse, mutect2, varscan2
- WNT9A | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV55297208, COSV99688302; called by muse, mutect2, varscan2
- XPA | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.088); catalogued as COSV64305738; called by muse, mutect2, varscan2
- ZDHHC4 | c.484T>A p.S162T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60107053; called by muse, mutect2, varscan2
- ZER1 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs148381372; called by muse, mutect2, varscan2
- ZNF143 | c.1505C>A p.S502Y | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV55182598; called by muse, mutect2, varscan2
- AXL | c.1135-4_1153del p.X379_splice | Splice Site (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel
- NCOA4 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- ZNF626 | c.567_571del p.T190* | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, varscan2
- AC008676.3 | c.141C>T p.S47= | Silent (SNP) | VAF 58/94 reads (62%) | catalogued as COSV56638068; called by muse, mutect2, varscan2
- ADAM17 | c.354C>T p.H118= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs373534760; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASCL1 | c.543C>T p.S181= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV57151901; called by muse, mutect2
- CYC1 | c.246G>C p.V82= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs538272583, COSV59645060; called by muse, mutect2, varscan2
- GABARAPL1 | c.246C>T p.N82= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV56771569; called by muse, mutect2, varscan2
- GBP4 | c.789T>C p.H263= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV63255969; called by muse, mutect2, varscan2
- GPR149 | c.1188C>T p.G396= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV67669962; called by muse, mutect2
- LRRC41 | c.1710G>C p.G570= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV58442401; called by muse, mutect2, varscan2
- NLGN4X | c.1371C>T p.A457= | Silent (SNP) | VAF 62/79 reads (78%) | catalogued as COSV52015083, COSV99320825; called by muse, mutect2, varscan2
- NLRP7 | c.534C>T p.G178= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as COSV100052181, COSV60181706; called by muse, mutect2, varscan2
- NPR2 | c.183C>T p.P61= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs777696337, COSV61310394; called by muse, mutect2, varscan2
- PKLR | c.1365C>T p.T455= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs146708702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF40A | c.288T>C p.P96= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV58444492; called by muse, mutect2, varscan2
- SIGLEC10 | c.1224G>A p.G408= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs1568498235, COSV59486492; called by muse, mutect2, varscan2
- SLC17A1 | c.705G>A p.K235= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV55082199, COSV99765743; called by muse, mutect2, varscan2
- SLC26A1 | c.1566C>T p.Y522= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs752562626, COSV56106410; called by muse, mutect2
- SLC45A2 | c.1134C>T p.S378= | Silent (SNP) | VAF 77/132 reads (58%) | catalogued as rs367806428, COSV99672920; called by muse, mutect2, varscan2
- SLITRK1 | c.903A>G p.P301= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV65677533; called by muse, mutect2
- TMEM171 | c.84C>T p.F28= | Silent (SNP) | VAF 58/85 reads (68%) | catalogued as rs752966920, COSV55129449; called by muse, mutect2, varscan2
- WDFY3 | c.4269T>C p.D1423= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV55713559; called by muse, mutect2, varscan2
- ZNF551 | c.1662T>A p.T554= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV56595037; called by muse, mutect2
- DCHS2 | n.1843A>G | RNA (SNP) | VAF 16/48 reads (33%) | catalogued as rs747985263, COSV59739219; called by muse, mutect2, varscan2
- VWF | c.55+308C>T | Intron (SNP) | VAF 42/89 reads (47%) | catalogued as rs1369875659, COSV99779845; called by muse, mutect2, varscan2
